Surgical pathology report (de-identified scan), TCGA case TCGA-CW-6097, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-CW-6097-01A (Primary Tumor).

TCGA-CW-6097

Surgical Pathology

REVISED REPORT (Addendum/Procedure included)

TISSUE DESCRIPTION:

13.5 cm segment left ureter and kidney (13.5 x 5.5 x 4.0 cm) (overall

- 430 grams, 17.0 x 9.0 x 5.5 cm)

DIAGNOSIS:

Kidney, left, nephrectomy: Grade 4 (of 4) renal cell carcinoma with sarcomatoid features, clear cell type, forms a 4.0 x 3.8 x 2.8 cm

mass located in the inferior pole of the kidney. The tumor extends into the pelvic fat. The renal vein is grossly free of tumor. The tumor does not involve the collecting system. Coagulative tumor

necrosis is present. The surgical margins are negative for tumor.

No renal hilar lymph nodes are identified. The adrenal gland is absent.

ADDENDUM:

The tumor shows predominantly clear cell type, with a small percentage (10-15%) showing sarcomatoid features.

PRELIMINARY FROZEN SECTION CONSULTATION:

Kidney, left, nephrectomy: HOLD OVER to further classify and grade renal tumor.

Source: NCI Genomic Data Commons file 93274279-0202-464b-abde-a2bdb127c7c0 (TCGA-CW-6097.4D777BBD-4E0C-4590-8632-4D3530B88D0F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).